Somatic mutation profile of tumor specimen MMRF_1143_2_BM_CD138pos (aliquot MMRF_1143_2_BM_CD138pos_T1_KHS5U_L08842) from MMRF case MMRF_1143, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.3 years (26,046 days).
Specimen MMRF_1143_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c0e5a12-2ee6-4da5-aab2-32583cbda5e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1143_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1143_2_PB_WBC_C2_KHS5U_L08810; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/286a6d97-849e-4eff-a56a-b3fa76403815

The open-access MAF lists 56 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, 3'UTR 18, Silent 8, Intron 4, RNA 3, 5'UTR 2, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH16A1 | c.1667G>A p.G556D | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1202810462; called by muse, mutect2
- BAZ1A | c.102C>A p.F34L | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV62409265; called by muse, mutect2
- IGKJ3 | c.27A>T p.K9N | Missense Mutation (SNP) | VAF 20/185 reads (11%) | catalogued as rs149374792; called by muse, varscan2
- IGLV3-1 | c.164A>T p.Q55L | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs543933563; called by muse, mutect2
- MSC | c.361C>G p.R121G | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1183172324, COSV100335893; called by muse, mutect2
- ZNF518A | c.743A>G p.E248G | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100283530; called by muse, mutect2
- BTNL3 | c.1339C>T p.H447Y | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- CCRL2 | c.842G>T p.S281I | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2
- CD79B | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- FBXO7 | c.400T>C p.W134R | Missense Mutation (SNP) | VAF 15/273 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- GNPTG | c.575A>T p.E192V | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGHV2-70D | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, varscan2
- LCT | c.1958A>T p.N653I | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); called by muse, mutect2
- OR2G3 | c.332A>C p.E111A | Missense Mutation (SNP) | VAF 22/337 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OXCT1 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); called by muse, mutect2
- PTPN2 | c.515T>C p.I172T | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RUBCN | c.1141T>C p.S381P | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC2A2 | c.1417C>A p.L473I | Missense Mutation (SNP) | VAF 17/399 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.236); called by muse, mutect2
- WNK2 | c.6829C>T p.R2277* | Nonsense Mutation (SNP) | VAF 30/307 reads (10%) | called by muse, mutect2
- ZFHX4 | c.1395A>T p.E465D | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); called by muse, mutect2
- ACTL7A | c.1122G>A p.L374= | Silent (SNP) | VAF 33/254 reads (13%) | catalogued as rs1379898392; called by muse, mutect2, varscan2
- GREB1 | c.2814C>T p.S938= | Silent (SNP) | VAF 18/254 reads (7%) | catalogued as COSV52194771; called by muse, mutect2
- MMRN2 | c.690A>G p.L230= | Silent (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- PCDHA2 | c.1267C>T p.L423= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- SEZ6L2 | c.975G>A p.E325= (on ENST00000308713 / NM_001114099.3; = p.E255= on NM_012410.4) | Silent (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- TULP1 | c.1425C>T p.Y475= | Silent (SNP) | VAF 18/245 reads (7%) | catalogued as rs1354544234; called by muse, mutect2
- ZER1 | c.2115C>G p.A705= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV52564788; called by muse, mutect2, varscan2
- ZNF618 | c.2460C>T p.Y820= (on ENST00000374126 / NM_001318042.2; = p.Y727= on NM_133374.2) | Silent (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- AC093890.1 | n.453T>C | RNA (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- ANTXR1 | c.952-6209G>C | Intron (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- BBS9 | c.*623G>A | 3'UTR (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- BNC2 | c.*1190T>G | 3'UTR (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- BTN1A1 | c.*1046C>T | 3'UTR (SNP) | VAF 16/223 reads (7%) | called by muse, mutect2
- C1orf21 | c.190-22298T>C | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- C1orf21 | c.*3057G>A | 3'UTR (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- ELP1 | c.*740T>C | 3'UTR (SNP) | VAF 22/206 reads (11%) | called by muse, mutect2, varscan2
- ELP1 | c.*393T>C | 3'UTR (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- FAM183BP | n.929del | RNA (DEL) | VAF 45/360 reads (13%) | called by mutect2, pindel, varscan2
- FSHB | c.*106G>T | 3'UTR (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2, varscan2
- GABRE | c.-16G>C | 5'UTR (SNP) | VAF 19/183 reads (10%) | called by muse, mutect2, varscan2
- HAND2 | c.*1111A>G | 3'UTR (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- IRF4 | c.*3725A>C | 3'UTR (SNP) | VAF 8/177 reads (5%) | called by muse, mutect2
- LYN | c.*730A>T | 3'UTR (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- MOB4 | c.*593A>G | 3'UTR (SNP) | VAF 27/393 reads (7%) | catalogued as rs1214147295; called by muse, mutect2
- MSL3 | c.383-65T>G | Intron (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- MST1L | n.3662T>G | RNA (SNP) | VAF 22/848 reads (3%) | catalogued as rs1325878218; called by muse, mutect2
- MYO10 | c.279+3348C>T | Intron (SNP) | VAF 3/51 reads (6%) | catalogued as rs1038034428; called by muse, mutect2
- NCKAP5 | c.*302G>A | 3'UTR (SNP) | VAF 4/72 reads (6%) | catalogued as rs1359087403; called by muse, mutect2
- NCOA3 | c.*3117G>A | 3'UTR (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- PRICKLE2 | c.*2827C>T | 3'UTR (SNP) | VAF 5/52 reads (10%) | called by mutect2, varscan2
- PSMG4 | chr6:3255209 G>A | 5'Flank (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- SESN3 | c.*4634A>G | 3'UTR (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- SLC25A26 | c.*959G>T | 3'UTR (SNP) | VAF 9/168 reads (5%) | called by muse, mutect2
- SLC25A45 | c.*9G>T | 3'UTR (SNP) | VAF 9/131 reads (7%) | called by muse, mutect2
- TMEM39A | c.*1359T>C | 3'UTR (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- ZNF430 | c.-38C>T | 5'UTR (SNP) | VAF 17/210 reads (8%) | catalogued as rs754654641; called by muse, mutect2
